Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88I, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88I-01A (Primary Tumor).

[page 1 of 5]
Page 1 of 1

Gender: Male	Birth Date:	Admit Date:
Attending:		Age:
		Location:

Surgical Pathology	Final Results
Surgical Pathology	Final

CASE NUMBER:
DIAGNOSIS:

1. Prostate, right margin, frozen section: Fibromuscular tissue, no tumor seen.
2. Seminal vesicles, portion of left, biopsy: Seminal vesicle, no tumor seen.
3. Lymph node, over anterior prostate, biopsy: Fibroadipose tissue, no lymph node identified.
4. Lymph nodes, right obturator packet, excision: Lymph nodes, no tumor seen (0/2).
5. Lymph nodes, right iliac, excision: Lymph nodes, no tumor seen (0/5).
6. Lymph nodes, left obturator packet, excision: Lymph nodes, no tumor seen (0/2).
7. Lymph nodes, left external iliac packet, excision: Lymph nodes, no tumor seen (0/2).
8. Soft tissue, adjacent to prostate base, excision: Muscle and transitional epithelium. A cluster of markedly abnormal but crushed prostatic cells is present. See Note.
9. Prostate, radical prostatectomy: Prostatic adenocarcinoma, predominant pattern Gleason score 8 (4 + 4) with areas of Gleason's score 9 (4 + 5) involving 45% of the left lobe and 20% of the right. Focal extracapsular invasion is present in the left side. Perineural invasion identified. Seminal vesicle free of tumor. Inked margins of resection are free of disease.

NOTE: A small cluster of abnormal epithelial cells is present. These cells stain positive for PSA suggesting prostatic origin. However, marked artifact makes definite diagnosis difficult. Case discussed with

SURGICAL PATHOLOGY CANCER SUMMARY TABLE

PROSTATE GLAND: Radical Prostatectomy

Procedure
Radical prostatectomy

Prostate Size
Weight: 42 g
Size: 4.5 x 3.5 x 3.6 cm

Lymph Node Sampling

100-0-3
Adenocarcinoma, acinar 8146/3
Site: Prostate NOS 061.9
9/10/7/13

[page 2 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
Pelvic lymph node dissection	
Histologic Type	
Adenocarcinoma (acinar, not otherwise specified)	
Histologic Grade	
Primary Pattern	
Grade 4	
Secondary Pattern	
Grade 4	
Tertiary Pattern	
Grade 5	
Total Gleason Score: 8	
Tumor Quantitation	
Proportion (percentage) of prostate involved by tumor: 45% of left lobe and 20% of right lobe	
Extraprostatic Extension	
Present	
Focal on left side	
Seminal Vesicle Invasion	
Not identified	
Margins	
Margins uninvolved by invasive carcinoma	
Treatment Effect on Carcinoma	
Lymph-Vascular Invasion	
Not identified	
Perineural Invasion	
Present	
Pathologic Staging (pTNM)	
Primary Tumor (pT)	
pT3a: Extraprostatic extension or microscopic invasion of bladder neck	
Regional Lymph Nodes (pN)	
pN0: No regional lymph node metastasis	
Number of Lymph Nodes Examined	
Specify: 11	
Distant Metastasis (pM)	
Not applicable	

[page 3 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: male with elevated psa and gleason 8 on biopsy

att: Specimen Taken For Protocol: - Yes
Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: prostate cancer Post-Operative Diagnosis:
same Operative Findings: normal anatomy

SPECIMENS SUBMITTED: 1. SERIAL 5+ 5FR.SLIDES, Right prostate margin
2. SEMINAL VESICLE, LEFT, Portion of
3. LYMPH NODES, Fat and lymph nodes over anterior prostate
4. OBTURATOR LYMPH NODE(S), Right
5. LYMPH NODES, Right iliac
6. OBTURATOR LYMPH NODE(S), Left
7. LYMPH NODES, Left external iliac LN packet
8. PROSTATE, Tissue adjacent to prostate base
9. PROSTATECTOMY, RADICAL

INTRAOPERATIVE CONSULTATION: Received fresh from the operating room labeled with the patient's name, medical record number, date of birth, and further specified as "right prostate margin" is a single pink to red fibrofatty soft tissue fragment measuring 0.2 x 0.2 x 0.2 cm. It is frozen in toto as 1FS.

1FS Diagnosis: No tumor seen, sympathetic ganglion and fibrovascular tissue. Five levels examined. The IOC is performed by and on

GROSS DESCRIPTION: Received are 9 formalin-filled container labeled with the patient's name, medical record number, medical record number and further specified as follows:

1. "Right prostate margin". It consists of a green cassette labeled with the patient's name and 1FS which contains a small soft tissue fragment wrapped in a tea bag which is entirely transferred to an orange cassette labeled
2. "Portion of left seminal vesicles". It consists of a tan soft

[page 4 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Final Results

9. "Prostate" consists of a prostatectomy specimen weighing 42 grams with the following measurements: Left to right 4.5, anterior to posterior 3.5 cm, apex to base 3.6 cm, left seminal vesicle 3.2 x 1 x 0.5 cm, left vas deferens 5 x 0.5 cm, right seminal vesicle 4.5 x 1.5 x 0.4 cm, right vas deferens 6 x 0.5 cm. The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two-thirds in blue, and left posterior two-thirds in red. Gross photographs are taken. One cut is made revealing a tan nodular cut surface and no discrete mass. Approximately 1 x 1 x 0.5 cm of tissue from the left side and approximately 1 x 1 x 0.5 cm of normal-appearing prostatic tissue from the central gland/P2 are procured for the

The procurement was performed by

The specimen is received in Pathology and matches the above description. Gross photographs are taken. The seminal vesicles and vas deferens are removed. The prostate is then placed into the pre-made mold and serially sectioned. Sections are placed into tea bags labeled

The right and left seminal vesicles and vas deferens are separated and the left seminal vesicle and vas deferens are serially

[page 5 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		ocation:

Surgical Pathology

Final Results

sectioned and placed into white cassettes labeled 9H-9J with 9H being in closest proximity to the prostate and 9J containing only vas deferens. The right seminal vesicle and vas deferens are then serially sectioned and placed into consecutive white cassettes labeled 9K-9M with 9K being in closest proximity to the prostate and 9M being most distal and containing mostly vas deferens.

Gross description dictated by
Description dictated by

Additional Gross

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

Resident

<Sign Out Dr. Signature>

Date Report Signed

Source: NCI Genomic Data Commons file ff6c8969-b4ad-47d4-b606-a70769f65b94 (TCGA-VN-A88I.571D4E0A-97DF-4B78-8F78-81DF0C040941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).